Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RI, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RI-01A (Primary Tumor).

ICD-O-3

Oligodendroglioma, grade II
9450/3

C66F

Site Brain, supratentorial NOS
C71.0

Brain, parietal lobe
C71.3

QW 10/4/13

Nature of material: Brain

Received on:

Macroscopy:

Received in formalin, brain parenchyma fragment weighing 2.0g and measuring 3.2 X 1.2 X 1.0 cm. Its outer surface is homogeneous and whitish. To cuts, shows up softened and brown-gray.

Microscopy:

Histological sections stained with H & E show fragments of neocortex with neuroepithelial neoplasm of white matter with marked cortical infiltration. The neoplastic cells have round nuclei, delicate chromatin and inconspicuous nucleoli. The cytoplasm is scant, indistinct, with frequent formation of perinuclear halos. The tumor infiltrates the cortex, where it is observed neuronal satellitosis by neoplastic cells and the formation of Scherer secondary structures in the subpial region. In some areas the tumor exhibits greater cellularity, where there are some microcysts. Mitotic figures are occasional. It was not observed vessels with microvascular proliferation in this material.

Diagnosis:

Excisional biopsy product of the left parietal tumor: - WHO grade II oligodendroglioma (ICD-O 9450/3).

PROFESSIONAL PARTICIPANTS OF REPORT

Source: NCI Genomic Data Commons file 03ea59b6-fd24-4efc-bbfb-a48f671a76ab (TCGA-TQ-A7RI.33BC8197-BDEB-4EC4-83A4-B871A8C0A094.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).